Somatic mutation profile of tumor specimen TCGA-VM-A8CE-01A (aliquot TCGA-VM-A8CE-01A-11D-A36O-08) from TCGA case TCGA-VM-A8CE, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Oligodendroglioma, NOS; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 25.6 years (9,363 days).
Specimen TCGA-VM-A8CE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 89710ba9-e529-43d7-8b6d-9b1dc9647567.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VM-A8CE-10A (Blood Derived Normal), aliquot TCGA-VM-A8CE-10A-01D-A367-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/eb2d2ddd-bde0-4f5c-8f44-c1d46ec8b30f

The open-access MAF lists 16 somatic variants for this specimen: 10 protein-altering or splice-affecting, 3 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 3, Intron 2, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CIC | c.604C>T p.R202W | Missense Mutation (SNP) | VAF 6/36 reads (17%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1344635105, COSV50573658; called by muse, varscan2
- CIC | c.643C>T p.R215W | Missense Mutation (SNP) | VAF 6/48 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1568504941, COSV50547203; ClinVar: likely pathogenic; called by muse, varscan2
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 28/105 reads (27%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- BAZ1B | c.3585G>T p.E1195D | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT tolerated (0.66); PolyPhen benign (0.028); catalogued as COSV59993296; called by muse, mutect2
- CIC | c.638G>C p.R213P | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50549905, COSV50559779; called by muse, varscan2
- NAE1 | c.1259A>T p.D420V | Missense Mutation (SNP) | VAF 21/169 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV99323369; called by muse, mutect2, varscan2
- NBEA | c.4092G>T p.K1364N | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.987); catalogued as COSV100085005; called by muse, mutect2
- SVEP1 | c.7061T>C p.V2354A | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.83); PolyPhen benign (0.009); catalogued as COSV99930052; called by muse, mutect2, varscan2
- TRPM6 | c.707G>A p.S236N | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100667105; called by muse, mutect2, varscan2
- ZNF554 | c.1596C>G p.N532K | Missense Mutation (SNP) | VAF 28/92 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.017); catalogued as rs1350520422, COSV100421363; called by muse, mutect2, varscan2
- EI24 | c.879C>G p.L293= | Silent (SNP) | VAF 6/21 reads (29%) | catalogued as COSV99629003, COSV99629274; called by muse, mutect2, varscan2
- MAP3K4 | c.4275G>A p.G1425= | Silent (SNP) | VAF 23/71 reads (32%) | catalogued as COSV100815747; called by muse, mutect2, varscan2
- SAP130 | c.1980C>G p.P660= | Silent (SNP) | VAF 30/102 reads (29%) | catalogued as COSV52097793, COSV99385496; called by muse, mutect2, varscan2
- ELMOD1 | c.-86+1040C>A | Intron (SNP) | VAF 4/59 reads (7%) | catalogued as COSV99760066, COSV99760536; called by muse, mutect2
- UGT1A6 | c.862-23432G>A | Intron (SNP) | VAF 24/97 reads (25%) | catalogued as rs1559387317, COSV100531261; called by muse, mutect2, varscan2
- XIST | n.7384C>T | RNA (SNP) | VAF 8/114 reads (7%) | catalogued as rs1314885615; called by muse, mutect2
